Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MC-01A (Primary Tumor).

1 CD-0-3

adenocarcinoma, endometrioid, NOS
8380/3

Site: endometrium c54.1

ju 5/3/11

FINAL DIAGNOSIS:

UTERUS AND CERVIX, BILATERAL ADNEXA, MICROSCOPIC ASSISTED VAGINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY (166 GRAMS) -

- A. WELL DIFFERENTIATED ENDOMETRIOID TYPE ENDOMETRIAL ADENOCARCINOMA (see comment).
- B. INVASIVE TUMOR IS CONFINED TO AN ENDOMETRIAL POLYP AND MEASURES 3.3 CM IN GREATEST DIMENSION; THE POLYP INVOLVES APPROXIMATELY 20% OF THE POSTERIOR UTERINE WALL.
- C. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- D. EXTENSIVE COMPLEX ATYPICAL ENDOMETRIAL HYPERPLASIA.
- E. CERVIX WITH BENIGN ENDOCERVICAL POLYP, NEGATIVE FOR NEOPLASM.
- F. LEFT AND RIGHT OVARIES WITH PHYSIOLOGIC CHANGES, NEGATIVE FOR NEOPLASM.
- G. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYST, NEGATIVE FOR NEOPLASM.
- H. LEFT OVARY WITH OLD SUTURE GRANULOMA, NEGATIVE FOR NEOPLASM.

COMMENT:

Cross refer pelvic wash specimen [REDACTED] which was negative for malignant cells. Previous diagnosis of complex atypical hyperplasia is noted [REDACTED]. Portions of this case were reviewed by [REDACTED], who agrees with the above interpretation.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

ARCHITECTURAL GRADE: Well differentiated

NUCLEAR GRADE: Grade 2

TUMOR SIZE: Maximum dimension: 3.3 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 0 %, Posterior endomyometrium: 20 %

DEPTH OF INVASION**: No invasion

MARGINS OF RESECTION: Vaginal margin is negative for tumor, Parametrium margin is negative for tumor

ANGIOLYMPHATIC INVASION: No

PRE-NEOPLASTIC CONDITIONS: Complex endometrial hyperplasia with atypia

OTHER: (epithelial, smooth muscle, others), Endometrial polyp

LYMPH NODES POSITIVE: Number of lymph nodes positive: 0

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 0

T STAGE, PATHOLOGIC: pT1a

N STAGE, PATHOLOGIC: pNX

M STAGE, PATHOLOGIC: pMX

FIGO STAGE: IA

Comment: Tumor invasion confined to endometrial polyp.

ju 5/3/11

Source: NCI Genomic Data Commons file 1221c395-0678-4cf0-aa01-4cdb79e03cc8 (TCGA-BG-A0MC.100F4900-491A-438B-9704-51D4E016B325.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).